TCGA case TCGA-UT-A88C — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Asbestos Diseases Research Institute. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b1f27fa2-133c-42c0-b69e-815af67e2a7e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 62 years; Vital status: Dead; Days to death: 863 days (2.4 years).

Diagnoses (2)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 63.0 years (23,002 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior treatment: No; Residual disease: R0; Days to last follow up: 863 days (2.4 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 24 days; Days to treatment end: 66 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 189 days; Days to treatment end: 232 days; Treatment dose: 45 Gy; Treatment outcome: Complete Response; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 189 days; Days to treatment end: 232 days; Treatment dose: 54 Gy; Treatment outcome: Complete Response; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Mediastinum, NOS. Age at diagnosis: 64.3 years (23,481 days); Days to diagnosis: 479 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (6 entries)
- Day 479 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Mediastinum, NOS; Days to progression: 479 days (1.3 years).
- Days to follow up: 577 days (1.6 years); Disease response: With Tumor.
- Days to follow up: 723 days (2.0 years); Disease response: With Tumor.
- Days to follow up: 863 days (2.4 years); Disease response: With Tumor.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Preoperative.
- ECOG performance status: 0; Timepoint: Preoperative.

Molecular and laboratory tests
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.45; Blood test normal range upper: 1.36].

Exposures
- Occupation duration years: 40; Occupation type: Armed Forces Occupations, Other Ranks.
- Exposure type: Asbestos; Age at last exposure: 32; Age at onset: 16; Exposure duration years: 15; Exposure source: Occupational.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UT-A88C-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-UT-A88C-01B-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 5.
- Sample TCGA-UT-A88C-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UT-A88C-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Navy Personnel.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 863 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 863 days; disease-free interval: event (new tumor event after initially disease-free), 479 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 479 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UT-A88C-01B-11D-A39Q-01): tumor purity 0.36, ploidy 2.23, whole-genome doublings 0.
